Somatic mutation profile of tumor specimen TCGA-K4-A6FZ-01A (aliquot TCGA-K4-A6FZ-01A-11D-A31L-08) from TCGA case TCGA-K4-A6FZ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 75.8 years (27,686 days).
Specimen TCGA-K4-A6FZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6856fffe-81df-4469-912a-8b1f14088e07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-K4-A6FZ-10A (Blood Derived Normal), aliquot TCGA-K4-A6FZ-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8cadc59-c438-45a3-b113-57861b3d0536

The open-access MAF lists 446 somatic variants for this specimen: 341 protein-altering or splice-affecting, 95 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 301, Silent 95, Nonsense Mutation 21, Intron 5, Splice Site 5, Frame Shift Del 5, Frame Shift Ins 4, 5'UTR 3, Splice Region 3, RNA 2, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 74/320 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB4 | c.2393T>C p.L798P | Missense Mutation (SNP) | VAF 23/114 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100725903, COSV61483358, COSV61493836; called by muse, mutect2, varscan2
- RB1 | c.1128-2A>G p.X376_splice | Splice Site (SNP) | VAF 35/109 reads (32%) | catalogued as rs1131690892, CS145469, COSV57306578, COSV57311966; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 21/56 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.776A>T p.D259V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs745425759, COSV52677009, COSV52679505, COSV53544033; ClinVar: uncertain significance; called by muse, mutect2
- ABCA12 | c.2813A>T p.E938V (on ENST00000272895 / NM_173076.3; = p.E620V on NM_015657.3) | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV55953459, COSV55963121; called by muse, mutect2, varscan2
- ABR | c.976G>A p.D326N (on ENST00000302538 / NM_021962.5; = p.D289N on NM_001092.5) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52141893; called by muse, mutect2, varscan2
- ACTR10 | c.1241C>T p.S414F | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV54298803; called by muse, mutect2, varscan2
- ACTR5 | c.1039A>T p.I347L | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV54761116; called by muse, mutect2, varscan2
- ADAM21 | c.734T>A p.M245K | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV50797033; called by muse, mutect2, varscan2
- ADAMTS16 | c.1031T>G p.L344R | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56993552; called by muse, mutect2, varscan2
- ADAMTS2 | c.3229T>C p.S1077P | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as COSV52379391; called by muse, mutect2, varscan2
- ADAMTS6 | c.97+2T>A p.X33_splice | Splice Site (SNP) | VAF 49/160 reads (31%) | catalogued as COSV66861062; called by muse, mutect2, varscan2
- ADGRL1 | c.1907G>A p.W636* (on ENST00000340736 / NM_001008701.3; = p.W631* on NM_014921.5) | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100529509; called by muse, mutect2, varscan2
- ADGRV1 | c.16959G>A p.M5653I | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV67987770; called by muse, mutect2, varscan2
- AFAP1L2 | c.2162A>T p.E721V | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as COSV58415826; called by muse, mutect2, varscan2
- AHCYL1 | c.1164G>A p.M388I | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV63208905; called by muse, mutect2, varscan2
- AKAP6 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 44/252 reads (17%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.985); catalogued as COSV55217606; called by muse, mutect2, varscan2
- AKAP6 | c.4657A>G p.M1553V | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.001); catalogued as COSV55217620; called by muse, mutect2, varscan2
- AKNA | c.3406A>G p.T1136A | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV56337817; called by muse, mutect2, varscan2
- AL592490.1 | c.1941dup p.V648Cfs*3 | Frame Shift Ins (INS) | VAF 12/69 reads (17%) | catalogued as rs1398443348; called by mutect2, pindel, varscan2
- ALYREF | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 14/91 reads (15%) | catalogued as COSV100485788, COSV100485841; called by muse, mutect2, varscan2
- AMER1 | c.2260C>T p.P754S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV57656940; called by muse, mutect2, varscan2
- AMER2 | c.767C>A p.P256Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.046); catalogued as COSV63438327; called by muse, varscan2
- ANAPC1 | c.811C>G p.L271V | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as COSV100594704; called by muse, mutect2, varscan2
- ANGPTL3 | c.755G>C p.R252T | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV52003813, COSV52009898; called by muse, varscan2
- AR | c.2045A>T p.E682V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101018205; called by muse, mutect2
- ARHGAP22 | c.803A>G p.E268G | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50949248; called by muse, mutect2, varscan2
- ARHGEF7 | c.2321C>G p.S774C (on ENST00000375741 / NM_001113511.2; = p.S753C on NM_145735.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV54545168; called by muse, mutect2, varscan2
- ASPM | c.485C>G p.S162C | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54131990; called by muse, mutect2
- ATP6V0A1 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV52872511; called by muse, mutect2, varscan2
- ATP6V1E1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as COSV53658580; called by muse, mutect2, varscan2
- BABAM1 | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV63921022; called by muse, mutect2
- BACH2 | c.1543A>G p.T515A | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.556); catalogued as COSV57596519; called by muse, mutect2, varscan2
- BCL9L | c.2840C>T p.S947L | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs139195814; called by muse, mutect2, varscan2
- BEX1 | c.299A>C p.Q100P | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65580329; called by muse, mutect2, varscan2
- BHLHE22 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.695); catalogued as COSV100417742; called by muse, mutect2, varscan2
- BIRC6 | c.11962A>G p.T3988A | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as rs1409886275, COSV66042877; called by muse, mutect2
- BNC1 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs781606013, COSV61757843; called by muse, varscan2
- BNC1 | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as rs776468517, COSV61757850; called by muse, varscan2
- BRCA2 | c.1142A>G p.D381G | Missense Mutation (SNP) | VAF 42/320 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.948); catalogued as rs769297468, COSV66455627; ClinVar: uncertain significance; called by muse, mutect2
- BRI3BP | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV58296406; called by muse, mutect2, varscan2
- BRPF3 | c.3487G>A p.D1163N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60208047; called by muse, mutect2, varscan2
- CAAP1 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.344); catalogued as COSV61700963; called by muse, varscan2
- CABP5 | c.272A>G p.E91G | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as COSV53153020; called by muse, mutect2, varscan2
- CALCB | c.180G>A p.M60I | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as COSV60834576; called by muse, mutect2, varscan2
- CAMK1G | c.256A>G p.I86V | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.075); catalogued as COSV50522932; called by muse, mutect2, varscan2
- CASP5 | c.605A>T p.K202M | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV52829275; called by muse, mutect2, varscan2
- CASZ1 | c.425A>G p.D142G | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV59737071; called by muse, mutect2, varscan2
- CBLL2 | c.118G>T p.D40Y | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV60369308; called by muse, mutect2, varscan2
- CCDC54 | c.553T>G p.S185A | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as COSV53758930; called by muse, mutect2, varscan2
- CCDC57 | c.176A>G p.Y59C | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1055026243, COSV66434534; called by muse, mutect2, varscan2
- CCR8 | c.791A>G p.H264R | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.023); catalogued as COSV100413075; called by muse, mutect2
- CD1D | c.362A>C p.E121A | Missense Mutation (SNP) | VAF 36/257 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV100939687, COSV63809233; called by muse, mutect2, varscan2
- CD1D | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 38/299 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs767850265, COSV100939534, COSV63809237; called by muse, mutect2, varscan2
- CDC42BPA | c.4033C>G p.Q1345E (on ENST00000334218 / NM_001366019.2; = p.Q1332E on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs775695070, COSV62013293, COSV62013706; called by muse, mutect2, varscan2
- CDH4 | c.2354A>C p.E785A | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV64659143; called by muse, mutect2, varscan2
- CENPE | c.7366G>A p.E2456K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV54382961; called by muse, mutect2
- CHD2 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV67710663; called by muse, mutect2, varscan2
- CHD4 | c.4528G>C p.E1510Q (on ENST00000357008 / NM_001363606.2; = p.E1523Q on NM_001273.5) | Missense Mutation (SNP) | VAF 66/188 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV58903579; called by muse, mutect2, varscan2
- CHRM2 | c.931T>A p.S311T | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as COSV57775216; called by muse, mutect2, varscan2
- CHURC1 | c.257-1G>A p.X86_splice (on ENST00000549115 / NM_001204063.1; = p.D87N on NM_145165.3) | Splice Site (SNP) | VAF 68/214 reads (32%) | catalogued as COSV63036382; called by muse, mutect2, varscan2
- CLEC7A | c.487G>A p.E163K (on ENST00000304084 / NM_197947.3; = p.E117K on NM_022570.5) | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53722727; called by muse, mutect2, varscan2
- CLTC | c.1526G>C p.G509A | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV52248899; called by muse, mutect2, varscan2
- CLU | c.1031T>A p.L344Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57067053; called by muse, mutect2, varscan2
- CMYA5 | c.5942C>T p.S1981F | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV71406656; called by muse, mutect2, varscan2
- CNTN4 | c.694C>A p.P232T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV61874981; called by muse, mutect2, varscan2
- CNTNAP1 | c.2254C>G p.L752V | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52851428; called by muse, mutect2, varscan2
- COL22A1 | c.1088A>G p.D363G | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as COSV57342513; called by muse, mutect2, varscan2
- COL4A1 | c.4817A>T p.E1606V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65427381; called by muse, mutect2, varscan2
- COL4A6 | c.3832C>A p.P1278T | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.871); catalogued as COSV57869266; called by muse, mutect2, varscan2
- COL8A1 | c.2159C>A p.S720* | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | catalogued as COSV99657701; called by muse, mutect2, varscan2
- CORIN | c.1293T>A p.N431K | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV56693258; called by muse, mutect2, varscan2
- CORO7 | c.1286C>G p.S429C | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV99227634; called by muse, mutect2, varscan2
- CRTC3 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs773913638, COSV51597573; called by muse, mutect2, varscan2
- CSF1 | c.1118T>C p.V373A | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60033889; called by muse, mutect2, varscan2
- CTNNA2 | c.1257A>C p.Q419H | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.243); catalogued as COSV58157947, COSV58167835; called by muse, mutect2
- CUX2 | c.4447G>C p.E1483Q | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55632735, COSV55636357; called by muse, mutect2, varscan2
- DCAF4L2 | c.613T>C p.S205P | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV60479679; called by muse, mutect2, varscan2
- DDX11 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV52505893; called by muse, mutect2, varscan2
- DDX31 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.289); catalogued as COSV100140108; called by muse, mutect2
- DIO3 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV63773876; called by muse, mutect2
- DNAH8 | c.2445A>C p.E815D | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV59455171; called by muse, mutect2, varscan2
- DNAI2 | c.533T>A p.L178* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as COSV100209769; called by muse, mutect2, varscan2
- DRC1 | c.1727G>C p.S576T | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV55506319; called by muse, mutect2, varscan2
- DTNBP1 | c.489-2A>G p.X163_splice | Splice Site (SNP) | VAF 14/26 reads (54%) | catalogued as COSV100160780; called by muse, mutect2, varscan2
- DUSP21 | c.542A>T p.E181V | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.772); catalogued as COSV59134369; called by muse, mutect2, varscan2
- DYRK4 | c.1204C>A p.Q402K | Missense Mutation (SNP) | VAF 55/208 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV50538518, COSV50540366, COSV50541077; called by muse, mutect2, varscan2
- DZIP1 | c.458A>G p.H153R | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.08); catalogued as COSV61266619; called by muse, mutect2, varscan2
- DZIP3 | c.968T>C p.V323A | Missense Mutation (SNP) | VAF 43/253 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV64312515; called by muse, mutect2, varscan2
- EIF4G3 | c.4324G>A p.E1442K | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV51685151; called by muse, mutect2, varscan2
- EIF5A | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 59/294 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV59750555; called by muse, mutect2, varscan2
- EMILIN3 | c.1366T>A p.L456M | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60036921; called by muse, mutect2, varscan2
- ENAM | c.2061A>T p.E687D | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.149); catalogued as COSV68536214; called by muse, mutect2, varscan2
- EP400 | c.3781C>T p.H1261Y | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57775626; called by muse, mutect2, varscan2
- ERBB3 | c.2773G>C p.E925Q | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57246944, COSV57256094; called by muse, mutect2, varscan2
- ERC2 | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as rs201400364, COSV55631219; called by muse, mutect2, varscan2
- ERCC6L | c.1453T>A p.S485T | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57821019; called by muse, mutect2, varscan2
- ERO1A | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 22/181 reads (12%) | catalogued as COSV101193622; called by muse, mutect2, varscan2
- FAM71F2 | c.498C>A p.F166L | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.671); catalogued as COSV66352203; called by muse, mutect2, varscan2
- FAM83G | c.262C>G p.Q88E | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs969896084, COSV58756629, COSV58759158; called by muse, mutect2
- FERD3L | c.272G>T p.R91L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs762682650, COSV51763141, COSV51764984; called by muse, mutect2, varscan2
- FERMT3 | c.317A>G p.N106S | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV54180867; called by muse, mutect2
- FFAR3 | c.838T>A p.S280T | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100588195; called by muse, varscan2
- FPR3 | c.346A>G p.I116V | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV59330393; called by muse, mutect2, varscan2
- FRMD4B | c.1124A>G p.E375G | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV68330857; called by muse, mutect2, varscan2
- FRMPD1 | c.1772A>G p.D591G | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV66700784; called by muse, mutect2, varscan2
- GABRA2 | c.668A>G p.Q223R | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as COSV62915992; called by muse, mutect2, varscan2
- GABRG2 | c.1303A>G p.T435A (on ENST00000361925 / NM_001375343.1; = p.T395A on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as rs757868774, COSV62719008; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- GAL3ST3 | c.584A>G p.E195G | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as COSV61749154; called by muse, varscan2
- GAL3ST3 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.316); catalogued as COSV61749159; called by muse, varscan2
- GALNT18 | c.806A>T p.K269M | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV57151163, COSV57152351; called by muse, mutect2, varscan2
- GALNTL6 | c.904G>C p.D302H | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.896); catalogued as COSV72491525; called by muse, mutect2
- GATA3 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1477514775, COSV60516838; called by muse, mutect2, varscan2
- GC | c.567C>A p.C189* | Nonsense Mutation (SNP) | VAF 22/765 reads (3%) | catalogued as COSV99909723; called by muse, mutect2
- GCNA | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV65467228; called by muse, mutect2, varscan2
- GMFB | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs760315736, COSV63737858; called by muse, mutect2, varscan2
- GOLGA2 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766471494, COSV68597312; called by muse, mutect2, varscan2
- GPI | c.1373A>T p.D458V | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV62894247; called by muse, mutect2, varscan2
- GPRIN2 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.009); catalogued as COSV65401290; called by muse, mutect2, varscan2
- GRIK5 | c.2494A>T p.R832W | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV53480345; called by muse, mutect2, varscan2
- HAUS5 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.889); catalogued as rs768994059, COSV52548319; called by muse, mutect2, varscan2
- HEATR5A | c.3616G>T p.V1206F | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV66342009; called by muse, mutect2, varscan2
- HERC1 | c.7031C>T p.S2344F | Missense Mutation (SNP) | VAF 91/300 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs1427972389, COSV71247223; called by muse, mutect2, varscan2
- HERC6 | c.1039C>T p.Q347* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as rs1209328133, COSV99910550; called by muse, mutect2, varscan2
- HGF | c.596A>T p.E199V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV55951427; called by muse, mutect2, varscan2
- HIPK1 | c.123A>T p.K41N | Missense Mutation (SNP) | VAF 170/555 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV65785394; called by muse, mutect2, varscan2
- HK3 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.259); catalogued as COSV52841371; called by muse, mutect2, varscan2
- HLCS | c.1737G>C p.K579N | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100358499, COSV60794683; called by muse, mutect2, varscan2
- HMCN1 | c.3911G>A p.G1304D | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54909344; called by muse, mutect2, varscan2
- HMGCS1 | c.650A>T p.D217V | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57290467; called by muse, mutect2, varscan2
- HNRNPH2 | c.439T>A p.F147I | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV54509609; called by muse, mutect2, varscan2
- HOOK3 | c.884A>G p.E295G | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56883653; called by muse, mutect2, varscan2
- HOXD12 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as COSV66832680; called by muse, mutect2, varscan2
- HSPA12A | c.858T>A p.N286K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.327); catalogued as COSV65022684; called by muse, mutect2, varscan2
- IFT74 | c.696G>C p.E232D | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV66259571; called by muse, mutect2, varscan2
- IGSF22 | c.689A>T p.E230V | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV60035379; called by muse, mutect2, varscan2
- INHBA | c.1066A>T p.S356C | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV54222505; called by muse, mutect2, varscan2
- IPMK | c.809A>G p.D270G | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.192); catalogued as COSV64243923; called by muse, mutect2, varscan2
- IPO4 | c.1973C>G p.S658* | Nonsense Mutation (SNP) | VAF 26/210 reads (12%) | catalogued as COSV100269014; called by muse, mutect2, varscan2
- IRS4 | c.2404T>A p.S802T | Missense Mutation (SNP) | VAF 39/292 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as COSV64534318; called by muse, mutect2, varscan2
- KCNF1 | c.617A>C p.E206A | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.135); catalogued as COSV54463980; called by muse, mutect2, varscan2
- KIAA0586 | c.4267G>C p.D1423H (on ENST00000619416 / NM_001244190.2; = p.D1362H on NM_014749.5) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV99708111; called by muse, mutect2, varscan2
- KIAA1549 | c.2417C>G p.S806* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99650732; called by muse, mutect2, varscan2
- KIAA1755 | c.1922A>T p.Q641L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as COSV54077489; called by muse, mutect2, varscan2
- KIF5B | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56653617; called by muse, mutect2, varscan2
- KLB | c.168T>A p.D56E | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV57302439; called by muse, mutect2, varscan2
- KLHL14 | c.1070T>C p.I357T | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.888); catalogued as rs753788704, COSV100839193; called by muse, mutect2
- KRT79 | c.1215G>C p.Q405H | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV57940552; called by muse, mutect2, varscan2
- KRTAP10-9 | c.133C>A p.L45M | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV59966841; called by muse, mutect2, varscan2
- KRTAP17-1 | c.174T>A p.C58* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100498566; called by muse, mutect2, varscan2
- LGALS14 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.107); catalogued as rs775909811, COSV62372280; called by muse, mutect2, varscan2
- LPP | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as rs926311103, COSV57096592; called by muse, varscan2
- LRRC66 | c.1301A>G p.H434R | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.053); catalogued as COSV58634452; called by muse, mutect2, varscan2
- LRRC7 | c.1650G>T p.Q550H (on ENST00000651989 / NM_001370785.2; = p.Q517H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV50482478; called by muse, mutect2, varscan2
- LRRC7 | c.2414A>C p.N805T (on ENST00000651989 / NM_001370785.2; = p.N772T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/241 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV50482578; called by muse, mutect2, varscan2
- LTBP1 | c.3826C>T p.Q1276* (on ENST00000404816 / NM_206943.4; = p.Q950* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | catalogued as COSV55384547, COSV99698252; called by muse, varscan2
- LZTR1 | c.1951C>G p.L651V | Missense Mutation (SNP) | VAF 394/580 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV53148429; called by muse, mutect2, varscan2
- MAGEA8 | c.251A>T p.D84V | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV54064332; called by muse, mutect2, varscan2
- MAGEC1 | c.1352T>C p.F451S | Missense Mutation (SNP) | VAF 36/324 reads (11%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.181); catalogued as rs751189520, COSV53568820; called by muse, mutect2
- MAGI2 | c.492G>A p.M164I | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.296); catalogued as rs555351741, COSV62670111; called by muse, mutect2, varscan2
- MAP2 | c.2006A>G p.E669G | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as COSV52295219; called by muse, mutect2, varscan2
- MAST1 | c.2936T>A p.F979Y | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52248670; called by muse, mutect2
- MC3R | c.362A>G p.D121G | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54764080; called by muse, mutect2, varscan2
- MED13 | c.5435G>C p.G1812A | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67264304; called by muse, mutect2, varscan2
- MEF2B | c.286G>C p.D96H | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV50765232, COSV99365217; called by muse, mutect2, varscan2
- MKI67 | c.3835G>C p.E1279Q | Missense Mutation (SNP) | VAF 65/212 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.111); catalogued as COSV64075031; called by muse, mutect2, varscan2
- MLXIPL | c.1511A>T p.K504I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV57668737; called by muse, mutect2, varscan2
- MMP27 | c.1473T>A p.Y491* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV99498426; called by muse, mutect2, varscan2
- MORC4 | c.1948A>G p.K650E | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV55243429; called by muse, mutect2, varscan2
- MPP6 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.117); catalogued as COSV56039620, COSV56040523; called by muse, mutect2, varscan2
- MSH6 | c.4000C>T p.R1334W | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs773763465, COSV52273496; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MSTN | c.1120T>C p.C374R | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53621356; called by muse, mutect2, varscan2
- MUC16 | c.37370A>G p.D12457G | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.996); catalogued as COSV67473884; called by muse, mutect2, varscan2
- MUC16 | c.21231A>T p.R7077S | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); catalogued as COSV67473888; called by muse, mutect2, varscan2
- MUC16 | c.2588G>A p.G863E | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.139); catalogued as COSV67473896; called by muse, mutect2, varscan2
- MXRA5 | c.995T>C p.L332S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54238981; called by muse, mutect2, varscan2
- MYH8 | c.3375C>G p.I1125M | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.318); catalogued as COSV67961904, COSV67967038; called by muse, mutect2, varscan2
- MYH8 | c.863T>C p.I288T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67967040; called by muse, mutect2, varscan2
- MYLK | c.1646T>A p.L549Q | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.938); catalogued as COSV60613148; called by muse, mutect2
- MYO18A | c.4968G>C p.K1656N | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV62868361; called by muse, mutect2, varscan2
- MYO1H | c.1042T>A p.C348S | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as COSV60446950; called by muse, mutect2, varscan2
- MYO3B | c.1392G>T p.L464F | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58706612; called by muse, mutect2
- NAA10 | c.59T>A p.L20H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.542); catalogued as COSV64170044; called by muse, mutect2, varscan2
- NCAM2 | c.1591C>T p.Q531* | Nonsense Mutation (SNP) | VAF 18/77 reads (23%) | catalogued as COSV99522923; called by muse, mutect2, varscan2
- NDST3 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56621325; called by muse, mutect2, varscan2
- NEDD8 | c.202C>T p.H68Y | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV51660258; called by muse, mutect2, varscan2
- NFRKB | c.2505G>C p.Q835H (on ENST00000446488 / NM_001143835.2; = p.Q860H on NM_006165.3) | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs778068389, COSV58758606; called by muse, mutect2, varscan2
- NKX2-1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV61388873, COSV61389072; called by muse, mutect2, varscan2
- NLRC5 | c.4380G>C p.E1460D | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV52657305; called by muse, mutect2, varscan2
- NLRC5 | c.4483G>C p.E1495Q | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as COSV52657322; called by muse, mutect2, varscan2
- NLRP13 | c.387A>T p.A129= | Splice Region (SNP) | VAF 14/71 reads (20%) | catalogued as COSV61622394; called by muse, mutect2, varscan2
- NLRP6 | c.1889A>G p.E630G | Missense Mutation (SNP) | VAF 76/281 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV56460327; called by muse, mutect2, varscan2
- NMD3 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.374); catalogued as COSV63618765; called by muse, mutect2, varscan2
- NOL4 | c.1545T>C p.D515= | Splice Region (SNP) | VAF 14/72 reads (19%) | catalogued as COSV99306405; called by muse, mutect2
- NOTCH2 | c.6723G>C p.L2241F | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.055); catalogued as COSV56694070; called by muse, mutect2, varscan2
- NPHS1 | c.1360A>C p.K454Q | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.079); catalogued as COSV62288462; called by muse, mutect2, varscan2
- NSG1 | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV67575224; called by muse, mutect2
- NTSR2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV100183829, COSV60991472; called by muse, mutect2, varscan2
- NUCB2 | c.968A>G p.E323G | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as rs757930720, COSV60375677; called by muse, mutect2, varscan2
- NUDT9 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765252270, COSV56197007; called by muse, mutect2, varscan2
- NWD1 | c.3836T>C p.V1279A | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as rs989923224, COSV60344391; called by muse, mutect2, varscan2
- NXF3 | c.283A>T p.K95* | Nonsense Mutation (SNP) | VAF 34/198 reads (17%) | catalogued as COSV101221940; called by muse, mutect2, varscan2
- OPHN1 | c.108C>G p.I36M | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV62783147; called by muse, mutect2, varscan2
- OR10G8 | c.309T>A p.F103L | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.701); catalogued as COSV70908286, COSV70908697; called by muse, mutect2
- OR10R2 | c.368T>C p.F123S | Missense Mutation (SNP) | VAF 79/351 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV63768977; called by muse, mutect2, varscan2
- OR13C5 | c.946T>A p.F316I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV101053100; called by muse, mutect2, varscan2
- OR13C9 | c.686A>T p.H229L | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV52242481; called by muse, mutect2, varscan2
- OR13H1 | c.871C>A p.L291M | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100088317, COSV58547834; called by muse, mutect2, varscan2
- OR2M5 | c.125A>G p.N42S | Missense Mutation (SNP) | VAF 103/451 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747013982, COSV63545534; called by muse, mutect2, varscan2
- OR4D11 | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 71/229 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV57586054; called by muse, mutect2, varscan2
- OR6K3 | c.586G>A p.D196N (on ENST00000368146; = p.D180N on NM_001005327.2) | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63745801; called by muse, mutect2, varscan2
- OR6V1 | c.812T>C p.V271A | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV69237388; called by muse, mutect2, varscan2
- OR8H1 | c.800T>A p.L267* | Nonsense Mutation (SNP) | VAF 16/98 reads (16%) | catalogued as COSV100477079; called by muse, mutect2, varscan2
- OTOL1 | c.97A>T p.K33* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100019968; called by muse, mutect2
- PABPC5 | c.1016A>C p.Q339P | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV57041388; called by muse, mutect2, varscan2
- PCDHA7 | c.1423T>C p.F475L | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV65344959; called by muse, mutect2, varscan2
- PCDHB11 | c.2281A>G p.T761A | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); catalogued as COSV61312255; called by muse, mutect2, varscan2
- PCK1 | c.1358G>C p.G453A | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs759756341, COSV60129028; called by muse, varscan2
- PCNX1 | c.5961A>T p.Q1987H | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53096425, COSV99455863; called by muse, mutect2
- PDS5B | c.2858A>G p.E953G | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV59728948; called by muse, mutect2, varscan2
- PEMT | c.287T>C p.L96P | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99703086; called by muse, mutect2
- PEX13 | c.120G>A p.M40I | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV54369963, COSV54370238; called by muse, mutect2
- PFKM | c.800T>C p.I267T | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as rs748720104, COSV56658213; called by muse, mutect2, varscan2
- PGC | c.142T>C p.Y48H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV63123023; called by muse, mutect2, varscan2
- PHKB | c.923A>T p.D308V | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as rs942136474, COSV54524359; called by muse, mutect2, varscan2
- PKP3 | c.1068G>A p.Q356= | Splice Region (SNP) | VAF 14/70 reads (20%) | catalogued as COSV58987657; called by muse, mutect2, varscan2
- PLB1 | c.1302C>G p.I434M | Missense Mutation (SNP) | VAF 60/240 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as rs538065102, COSV59828200; called by muse, mutect2, varscan2
- PLB1 | c.4052C>T p.S1351L | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59828228; called by muse, mutect2, varscan2
- PLCL2 | c.1313A>C p.N438T (on ENST00000615277 / NM_001144382.2; = p.N312T on NM_015184.5) | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.643); catalogued as COSV67622826; called by muse, mutect2, varscan2
- PLEKHA7 | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV63047422; called by muse, mutect2, varscan2
- PNKD | c.856C>A p.L286I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.642); catalogued as COSV99282388; called by muse, mutect2
- POU3F2 | c.1061A>C p.K354T | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60409187; called by muse, mutect2, varscan2
- POU4F2 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); catalogued as rs1255028715, COSV99850510; called by muse, mutect2
- PRDM16 | c.2886A>T p.R962S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54594776; called by muse, mutect2, varscan2
- PREX1 | c.3097T>A p.L1033M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.602); catalogued as COSV64253109; called by muse, mutect2, varscan2
- PRSS12 | c.1897G>T p.G633C | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1342545375, COSV56607161; called by muse, mutect2
- PTBP1 | c.141C>G p.F47L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.019); catalogued as COSV62460535; called by muse, varscan2
- PTPRJ | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV69252841; called by muse, varscan2
- R3HDM1 | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as rs766956578, COSV51526292; called by muse, mutect2, varscan2
- RABGGTA | c.386T>G p.L129R | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1372176259, COSV53770820; called by muse, mutect2, varscan2
- RALGAPB | c.1796C>T p.S599L | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.985); catalogued as COSV53439139; called by muse, varscan2
- RALGAPB | c.1940C>T p.S647F | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV53439161; called by muse, mutect2, varscan2
- RASGEF1A | c.767A>G p.D256G | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV65666990; called by muse, mutect2, varscan2
- RASGEF1C | c.253C>T p.H85Y | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV63181517; called by muse, mutect2, varscan2
- RASSF9 | c.1238C>A p.T413N | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63434326; called by muse, mutect2, varscan2
- RBAK | c.2105G>A p.R702K | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV62331730; called by muse, mutect2, varscan2
- RBMS3 | c.401A>G p.Q134R | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV56150621; called by muse, mutect2, varscan2
- RGS4 | c.448G>C p.D150H | Missense Mutation (SNP) | VAF 156/617 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100905561; called by muse, mutect2, varscan2
- RHOXF2B | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs782259815, COSV65054883; called by muse, mutect2, varscan2
- RIMBP2 | c.3100C>G p.Q1034E | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV55462957, COSV55472763, COSV55480417; called by muse, mutect2, varscan2
- RIN1 | c.2267C>G p.A756G | Missense Mutation (SNP) | VAF 71/261 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV60927230; called by muse, mutect2, varscan2
- RLIM | c.634A>T p.R212* | Nonsense Mutation (SNP) | VAF 22/174 reads (13%) | catalogued as COSV100222999; called by muse, mutect2, varscan2
- RNF123 | c.2710C>G p.L904V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57538982; called by muse, mutect2, varscan2
- RNF17 | c.1444C>G p.R482G | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55042556; called by muse, mutect2
- RNF213 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs1257976035, COSV100173612, COSV60625309; called by muse, mutect2, varscan2
- RTEL1 | c.2776G>A p.D926N | Missense Mutation (SNP) | VAF 89/340 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as rs369357121; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.12956T>A p.V4319D | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63691737; called by muse, mutect2, varscan2
- SAFB2 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV53043064; called by muse, mutect2, varscan2
- SDCCAG8 | c.548del p.X183_splice | Splice Site (DEL) | VAF 58/156 reads (37%) | catalogued as COSV100654737; called by mutect2, pindel, varscan2
- SDHAF3 | c.144C>G p.D48E | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs756006477, COSV64491460; called by muse, mutect2, varscan2
- SEC24B | c.2164A>G p.T722A | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.276); catalogued as COSV54501512; called by muse, mutect2, varscan2
- SETX | c.3203A>T p.E1068V | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV56387605, COSV56387817; called by muse, mutect2, varscan2
- SEZ6L | c.1640A>G p.D547G | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV50668074; called by muse, mutect2, varscan2
- SH3PXD2A | c.2515G>T p.E839* (on ENST00000369774 / NM_001365079.1; = p.E811* on NM_014631.2) | Nonsense Mutation (SNP) | VAF 32/99 reads (32%) | catalogued as COSV100280089; called by muse, mutect2, varscan2
- SLC1A6 | c.457A>T p.I153F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV55671306; called by muse, mutect2, varscan2
- SLC26A3 | c.94C>A p.H32N | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as COSV60640818; called by muse, mutect2, varscan2
- SLC5A3 | c.576G>A p.M192I | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV62970507; called by muse, mutect2, varscan2
- SLC66A3 | c.336G>C p.W112C | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV54467291; called by muse, mutect2, varscan2
- SLC7A1 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs763171472, COSV66330815; called by muse, mutect2, varscan2
- SLC8A1 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV60484814; called by muse, mutect2
- SLC9B2 | c.68C>A p.P23H | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.087); catalogued as COSV60019958; called by muse, mutect2, varscan2
- SLCO5A1 | c.1145A>G p.K382R | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as rs1430257385, COSV52661467; called by muse, mutect2, varscan2
- SLU7 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as COSV51788432, COSV51788828, COSV99775811; called by muse, mutect2, varscan2
- SNTG2 | c.1191G>C p.K397N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV57988996; called by muse, mutect2, varscan2
- SPOCK3 | c.1289A>T p.D430V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV62728369; called by muse, mutect2, varscan2
- SULF1 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); catalogued as COSV52684478; called by muse, mutect2, varscan2
- SV2A | c.1973T>C p.F658S | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV64965093; called by muse, mutect2, varscan2
- SV2A | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64965098; called by muse, mutect2, varscan2
- SYT14 | c.1337C>A p.A446E | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV55056915; called by muse, mutect2, varscan2
- SYT15 | c.556A>T p.K186* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV100970385; called by mutect2, varscan2
- SYTL2 | c.1180C>T p.Q394* | Nonsense Mutation (SNP) | VAF 12/105 reads (11%) | catalogued as COSV100314209; called by muse, mutect2, varscan2
- TAF1L | c.805A>G p.K269E | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs1401193369, COSV54263623; called by muse, mutect2, varscan2
- TAFA4 | c.157T>A p.C53S | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542438958, COSV55139622; called by muse, mutect2, varscan2
- TCEA2 | c.601A>T p.N201Y | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58658243; called by muse, mutect2, varscan2
- TCHH | c.4747T>A p.L1583I | Missense Mutation (SNP) | VAF 93/176 reads (53%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV64275552; called by muse, mutect2, varscan2
- TECRL | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1461388254, COSV67087841; called by muse, mutect2, varscan2
- TENT5D | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs199636557, COSV57638732; called by muse, mutect2
- TICAM1 | c.1192G>C p.V398L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV50233414; called by muse, mutect2, varscan2
- TIE1 | c.1463A>G p.D488G | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.161); catalogued as COSV65250105; called by muse, mutect2, varscan2
- TMEM144 | c.737A>G p.Y246C | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56701460; called by muse, mutect2, varscan2
- TNNC1 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as rs866734970, COSV51767860; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNNC1 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99234725, COSV99234833; called by muse, mutect2, varscan2
- TP53BP1 | c.4651G>A p.E1551K | Missense Mutation (SNP) | VAF 91/328 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55503354; called by muse, mutect2, varscan2
- TPRX1 | c.1054C>G p.H352D | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV59116387; called by muse, mutect2, varscan2
- TRABD2A | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59103822; called by muse, mutect2, varscan2
- TRIP12 | c.2222A>T p.E741V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV52266294; called by muse, mutect2, varscan2
- TRPA1 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs962446963, COSV51564530; called by muse, mutect2, varscan2
- TSC2 | c.2615C>T p.S872F | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1261671606, COSV54759455; called by muse, mutect2, varscan2
- TSPEAR | c.142A>G p.I48V | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59966834; called by muse, mutect2, varscan2
- TTN | c.50884C>T p.P16962S (on ENST00000591111; = p.P9538S on NM_003319.4) | Missense Mutation (SNP) | VAF 32/84 reads (38%) | PolyPhen benign (0.104); catalogued as COSV60134071; called by muse, mutect2, varscan2
- TTN | c.50540T>C p.V16847A (on ENST00000591111; = p.V9423A on NM_003319.4) | Missense Mutation (SNP) | VAF 71/202 reads (35%) | PolyPhen probably damaging (0.99); catalogued as COSV60134118; called by muse, mutect2, varscan2
- TTN | c.7513A>T p.N2505Y (on ENST00000591111; = p.N2459Y on NM_003319.4) | Missense Mutation (SNP) | VAF 36/74 reads (49%) | PolyPhen possibly damaging (0.814); catalogued as COSV60134168; called by muse, mutect2, varscan2
- TXNDC16 | c.1226A>G p.D409G | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.268); catalogued as COSV55985255; called by muse, mutect2, varscan2
- TYRP1 | c.923A>T p.D308V | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV66358056; called by muse, mutect2, varscan2
- UBASH3B | c.1375A>T p.S459C | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV52496647; called by muse, mutect2, varscan2
- UBE2M | c.107A>G p.K36R | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.946); catalogued as COSV99285214; called by muse, mutect2, varscan2
- UBR4 | c.12896C>G p.T4299S | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV64391983; called by muse, mutect2, varscan2
- UCP2 | c.310A>G p.K104E | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs754485408, COSV60104916; called by muse, mutect2, varscan2
- UNC13D | c.1489G>C p.D497H | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV52885306; called by muse, mutect2, varscan2
- USH1G | c.206del p.L69Rfs*26 | Frame Shift Del (DEL) | VAF 11/78 reads (14%) | catalogued as COSV58882284; called by mutect2, pindel, varscan2
- USH2A | c.924C>G p.H308Q | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56385895; called by muse, mutect2, varscan2
- USP34 | c.3747G>C p.Q1249H | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.496); catalogued as COSV68402459, COSV68408009; called by muse, mutect2, varscan2
- VPS13A | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756947231, COSV62431931; called by muse, mutect2, varscan2
- VRK3 | c.1306A>G p.M436V | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as COSV57466208; called by muse, mutect2, varscan2
- WDR49 | c.384del p.N128Kfs*4 (on ENST00000308378 / NM_001366158.1; = p.N469Kfs*4 on NM_001348951.2 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 26/162 reads (16%) | catalogued as COSV57710367; called by mutect2, pindel*, varscan2
- WDR7 | c.2267A>G p.E756G | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.156); catalogued as COSV54355552; called by muse, mutect2, varscan2
- XRN2 | c.2620C>T p.P874S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.968); catalogued as COSV65870130; called by muse, mutect2, varscan2
- ZC3H12B | c.1933G>C p.E645Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV59049099; called by muse, mutect2, varscan2
- ZNF143 | c.413A>G p.E138G | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55180532; called by muse, mutect2, varscan2
- ZNF157 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.213); catalogued as COSV65658424; called by muse, mutect2, varscan2
- ZNF250 | c.1176G>C p.E392D | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV52969604; called by muse, mutect2, varscan2
- ZNF286A | c.488A>T p.E163V | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV67845817; called by muse, mutect2, varscan2
- ZNF507 | c.2054A>T p.E685V | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61331850; called by muse, mutect2, varscan2
- ZNF611 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV60540784; called by muse, mutect2, varscan2
- ZNF676 | c.1451A>G p.E484G (on ENST00000650058; = p.E452G on NM_001001411.3) | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV68093475; called by muse, mutect2, varscan2
- ZNF69 | c.359C>T p.S120F (on ENST00000429654 / NM_001364730.1; = p.S106F on NM_021915.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.606); catalogued as COSV60903769; called by muse, mutect2, varscan2
- BRWD3 | c.4226del p.K1409Sfs*7 | Frame Shift Del (DEL) | VAF 11/80 reads (14%) | called by mutect2, pindel, varscan2
- CLUH | c.2335_2338dup p.R780Hfs*32 (on ENST00000435359; = p.R819Hfs*32 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 21/85 reads (25%) | called by mutect2, pindel, varscan2
- EFHD2 | c.653G>C p.R218T | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2
- FCN2 | c.846del p.T283Lfs*26 | Frame Shift Del (DEL) | VAF 21/114 reads (18%) | called by mutect2, pindel, varscan2
- GFRA2 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, varscan2
- KMT2C | c.421dup p.E141Gfs*29 | Frame Shift Ins (INS) | VAF 12/98 reads (12%) | called by mutect2, pindel, varscan2
- LAS1L | c.1415C>T p.S472L | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- NBPF15 | c.1120G>A p.G374S | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.99); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PRAMEF5 | c.1363A>T p.T455S | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.987); called by muse, varscan2
- PRAMEF6 | c.1363A>T p.T455S | Missense Mutation (SNP) | VAF 41/361 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- ROBO3 | c.3407del p.P1136Hfs*103 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- SLC50A1 | c.231_234dup p.L79Cfs*46 | Frame Shift Ins (INS) | VAF 21/78 reads (27%) | called by mutect2, pindel, varscan2
- TMEM184B | c.304_306del p.F102del | In Frame Del (DEL) | VAF 19/66 reads (29%) | called by pindel, varscan2
- UROC1 | c.724A>G p.K242E | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- ACTR10 | c.385C>T p.L129= | Silent (SNP) | VAF 18/243 reads (7%) | catalogued as COSV54298791; called by muse, mutect2
- ADCY8 | c.3255T>C p.F1085= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV53912369; called by muse, mutect2, varscan2
- ADRA1A | c.93G>A p.V31= | Silent (SNP) | VAF 106/304 reads (35%) | catalogued as COSV52366060; called by muse, mutect2, varscan2
- AFF2 | c.144T>C p.F48= | Silent (SNP) | VAF 22/200 reads (11%) | catalogued as COSV60668929; called by muse, mutect2, varscan2
- AL035461.3 | c.2910C>T p.F970= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV66652068; called by muse, mutect2, varscan2
- ANO7 | c.1230C>T p.A410= (on ENST00000274979; = p.A356= on NM_001370694.2) | Silent (SNP) | VAF 50/122 reads (41%) | catalogued as COSV51473329; called by muse, mutect2, varscan2
- APOB | c.2976C>T p.Y992= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV51939893; called by muse, mutect2, varscan2
- ARNTL | c.309C>T p.N103= | Silent (SNP) | VAF 71/286 reads (25%) | catalogued as rs138340325; called by muse, mutect2, varscan2
- ATG4D | c.1290G>T p.L430= | Silent (SNP) | VAF 39/139 reads (28%) | catalogued as COSV57264952; called by muse, mutect2, varscan2
- BCORL1 | c.540A>G p.G180= | Silent (SNP) | VAF 20/181 reads (11%) | catalogued as COSV54398726; called by muse, mutect2, varscan2
- BNC1 | c.768G>A p.L256= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs1164173760, COSV61757865; called by muse, mutect2, varscan2
- CACNA1D | c.4878A>T p.G1626= (on ENST00000350061 / NM_001128840.3; = p.G1646= on NM_000720.4) | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV55451786; called by muse, mutect2, varscan2
- CACNA1D | c.5274C>G p.L1758= (on ENST00000350061 / NM_001128840.3; = p.L1778= on NM_000720.4) | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV55451804; called by muse, mutect2, varscan2
- CALN1 | c.141T>C p.V47= (on ENST00000329008 / NM_001017440.3; = p.V89= on NM_031468.4) | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV61137475; called by muse, mutect2, varscan2
- CCNB3 | c.2442T>A p.A814= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV52075031; called by muse, mutect2, varscan2
- CCNT1 | c.1354C>T p.L452= | Silent (SNP) | VAF 25/119 reads (21%) | catalogued as rs772728567, COSV56064678; called by muse, mutect2, varscan2
- CDH19 | c.1563C>T p.I521= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV50962335; called by muse, mutect2, varscan2
- CELA3B | c.663C>G p.L221= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV100448673, COSV61404423; called by muse, mutect2
- CEMIP2 | c.3183C>G p.V1061= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV65484264, COSV65485104; called by muse, mutect2, varscan2
- COL22A1 | c.2388A>G p.R796= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV100280672, COSV57342501; called by muse, mutect2, varscan2
- CPAMD8 | c.3231C>G p.L1077= (on ENST00000651564; = p.L1030= on NM_015692.5) | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV71596759; called by muse, mutect2, varscan2
- CRYL1 | c.186G>A p.L62= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV53418891; called by muse, mutect2, varscan2
- DOCK2 | c.2793T>A p.I931= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV56964667; called by muse, mutect2, varscan2
- ECD | c.396A>G p.E132= | Silent (SNP) | VAF 51/132 reads (39%) | catalogued as COSV65900191; called by muse, mutect2, varscan2
- EEF1A2 | c.1182G>A p.L394= | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as COSV53206694; called by muse, mutect2, varscan2
- ELF1 | c.1671C>T p.I557= | Silent (SNP) | VAF 42/113 reads (37%) | catalogued as COSV53499788; called by muse, mutect2, varscan2
- ENPP7 | c.1269A>G p.G423= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as COSV60386951; called by muse, mutect2, varscan2
- FAM155B | c.1278C>T p.L426= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV52936605, COSV52937822; called by muse, mutect2, varscan2
- FAM98C | c.720A>T p.T240= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV53039063; called by muse, mutect2, varscan2
- FAT3 | c.738G>T p.V246= | Silent (SNP) | VAF 66/227 reads (29%) | catalogued as COSV53126359; called by muse, mutect2, varscan2
- FFAR3 | c.877A>C p.R293= | Silent (SNP) | VAF 17/136 reads (13%) | catalogued as COSV100588196; called by muse, varscan2
- GSTA5 | c.552G>A p.L184= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as rs567319452, COSV52862261; called by muse, mutect2, varscan2
- HHIP | c.1395T>C p.I465= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as rs200057636, COSV56840561; called by muse, mutect2, varscan2
- HNF1A | c.807C>T p.A269= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV57463320; called by muse, mutect2, varscan2
- IKBKB | c.1437C>G p.L479= | Silent (SNP) | VAF 26/134 reads (19%) | catalogued as COSV60597892; called by muse, mutect2, varscan2
- INKA2 | c.12G>A p.E4= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV61878114; called by muse, mutect2, varscan2
- IRAG1 | c.2373T>C p.G791= | Silent (SNP) | VAF 45/142 reads (32%) | catalogued as COSV70211634; called by muse, mutect2, varscan2
- KMT2D | c.14148G>T p.G4716= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV56452616; called by muse, mutect2, varscan2
- LZTR1 | c.822C>T p.L274= | Silent (SNP) | VAF 37/56 reads (66%) | catalogued as COSV53148397; called by muse, mutect2, varscan2
- LZTR1 | c.1671C>T p.F557= | Silent (SNP) | VAF 180/257 reads (70%) | catalogued as rs148399643; called by muse, mutect2, varscan2
- MACF1 | c.15030C>T p.L5010= (on ENST00000372915; = p.L2943= on NM_012090.5) | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as rs369137678, COSV57127289; called by muse, mutect2, varscan2
- MAJIN | c.648C>T p.F216= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as COSV54164632; called by muse, mutect2, varscan2
- MAMLD1 | c.1974T>C p.H658= | Silent (SNP) | VAF 22/154 reads (14%) | catalogued as COSV53376624; called by muse, mutect2
- MANBA | c.756C>T p.I252= | Silent (SNP) | VAF 21/175 reads (12%) | catalogued as rs779421094, COSV56966492; called by muse, mutect2, varscan2
- MCM10 | c.439C>T p.L147= | Silent (SNP) | VAF 54/167 reads (32%) | catalogued as rs760727051, COSV66335018; called by muse, mutect2, varscan2
- MESP2 | c.978G>C p.L326= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV59092791; called by muse, mutect2, varscan2
- MPRIP | c.3063C>G p.V1021= | Silent (SNP) | VAF 114/393 reads (29%) | catalogued as rs1321686047, COSV57927997; called by muse, mutect2, varscan2
- MTSS1 | c.507C>G p.V169= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV61497819; called by muse, mutect2, varscan2
- MUC17 | c.2037A>T p.P679= | Silent (SNP) | VAF 94/626 reads (15%) | catalogued as COSV60292046; called by muse, mutect2, varscan2
- MYH10 | c.5040G>A p.K1680= | Silent (SNP) | VAF 31/149 reads (21%) | catalogued as COSV52603685; called by muse, mutect2, varscan2
- MYH11 | c.1536G>A p.G512= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as COSV55557006; called by muse, mutect2, varscan2
- MYO9A | c.6726G>C p.L2242= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100613462; called by muse, mutect2
- MYT1L | c.1497G>A p.K499= | Silent (SNP) | VAF 56/217 reads (26%) | catalogued as COSV67707758, COSV67722818; called by muse, mutect2, varscan2
- NEK4 | c.1836A>G p.P612= | Silent (SNP) | VAF 68/238 reads (29%) | catalogued as rs1008619273, COSV51781002; called by muse, mutect2, varscan2
- NUDCD2 | c.411T>C p.S137= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV57084922; called by muse, mutect2, varscan2
- OR10A2 | c.525C>T p.V175= | Silent (SNP) | VAF 40/186 reads (22%) | catalogued as COSV56299008; called by muse, mutect2, varscan2
- OR4L1 | c.669C>A p.V223= | Silent (SNP) | VAF 25/159 reads (16%) | catalogued as COSV59850292, COSV59850994; called by muse, mutect2, varscan2
- OR6F1 | c.136T>C p.L46= | Silent (SNP) | VAF 29/220 reads (13%) | catalogued as COSV57466876, COSV57469141; called by muse, mutect2, varscan2
- OR7A10 | c.84T>C p.F28= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as COSV50166450; called by muse, mutect2, varscan2
- PIK3R6 | c.711C>G p.A237= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV100266448; called by muse, mutect2, varscan2
- PNLIPRP1 | c.132T>A p.I44= | Silent (SNP) | VAF 74/190 reads (39%) | catalogued as COSV62612194; called by muse, mutect2, varscan2
- POLRMT | c.3180C>T p.L1060= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV99241784; called by muse, mutect2
- PROKR1 | c.699C>T p.F233= | Silent (SNP) | VAF 14/140 reads (10%) | catalogued as COSV58137952; called by muse, mutect2, varscan2
- PRTFDC1 | c.231A>T p.G77= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as COSV60775296; called by muse, mutect2
- RALGAPB | c.1851C>T p.I617= | Silent (SNP) | VAF 51/248 reads (21%) | catalogued as COSV53439150; called by muse, varscan2
- RIBC2 | c.240C>T p.I80= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV61581731; called by muse, mutect2, varscan2
- RLIM | c.633A>T p.A211= | Silent (SNP) | VAF 24/175 reads (14%) | catalogued as rs773335683, COSV60327271; called by muse, mutect2, varscan2
- ROBO3 | c.969G>A p.T323= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs201966716, COSV67300035; called by muse, mutect2, varscan2
- RPA1 | c.1593T>C p.C531= | Silent (SNP) | VAF 36/124 reads (29%) | catalogued as COSV54610229; called by muse, mutect2, varscan2
- RPS7 | c.369A>T p.T123= | Silent (SNP) | VAF 46/189 reads (24%) | catalogued as COSV59233050; called by muse, mutect2, varscan2
- SACS | c.10695A>G p.K3565= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV66541782; called by mutect2, varscan2
- SEC63 | c.834C>A p.I278= | Silent (SNP) | VAF 41/106 reads (39%) | catalogued as COSV64600353; called by muse, mutect2, varscan2
- SLC17A6 | c.1464T>C p.Y488= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs767741052, COSV54137559; called by muse, mutect2, varscan2
- SUCLA2 | c.798A>G p.G266= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as COSV66222391; called by muse, mutect2, varscan2
- TCOF1 | c.1362A>T p.A454= (on ENST00000377797 / NM_001135243.1; = p.A377= on NM_000356.4) | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV60349853; called by muse, mutect2, varscan2
- TMC1 | c.879C>G p.L293= | Silent (SNP) | VAF 46/202 reads (23%) | catalogued as rs772213890, COSV52777684; called by muse, mutect2, varscan2
- TMEM164 | c.192G>A p.T64= | Silent (SNP) | VAF 22/152 reads (14%) | catalogued as rs201823249, COSV55813120; called by muse, mutect2, varscan2
- TNR | c.1167C>T p.L389= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs1319073589, COSV54892060; called by muse, mutect2, varscan2
- TTN | c.63684T>C p.G21228= (on ENST00000591111; = p.G13804= on NM_003319.4) | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs772421669, COSV60133986; called by muse, mutect2, varscan2
- TTN | c.51438T>A p.P17146= (on ENST00000591111; = p.P9722= on NM_003319.4) | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV60134030; called by muse, mutect2, varscan2
- TTN | c.4254T>C p.S1418= (on ENST00000591111; = p.S1372= on NM_003319.4) | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs764984200, COSV60134223; called by muse, mutect2, varscan2
- TUBA3C | c.309C>T p.Y103= | Silent (SNP) | VAF 25/157 reads (16%) | catalogued as rs114178008, COSV67139668; called by muse, mutect2, varscan2
- TYK2 | c.573C>G p.L191= | Silent (SNP) | VAF 30/142 reads (21%) | catalogued as COSV53388350; called by muse, mutect2, varscan2
- UBR1 | c.2847A>G p.G949= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as COSV51931412; called by muse, mutect2, varscan2
- UBR1 | c.2139G>A p.Q713= | Silent (SNP) | VAF 71/215 reads (33%) | catalogued as COSV51931420; called by muse, mutect2, varscan2
- UFSP2 | c.1089G>A p.L363= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV52991904; called by muse, mutect2, varscan2
- USP26 | c.1590T>C p.C530= | Silent (SNP) | VAF 26/224 reads (12%) | catalogued as COSV63708946; called by muse, mutect2, varscan2
- USP32 | c.3342G>A p.R1114= | Silent (SNP) | VAF 41/151 reads (27%) | catalogued as COSV56270605; called by muse, mutect2, varscan2
- VPS13B | c.10884G>A p.A3628= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as rs768029540, COSV62137624; ClinVar: likely benign; called by muse, mutect2, varscan2
- VWA3B | c.3516A>T p.P1172= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as COSV71367585; called by muse, mutect2, varscan2
- XCR1 | c.930G>C p.L310= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV58569798; called by muse, mutect2, varscan2
- ZC3H12C | c.609A>G p.G203= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs1488890396, COSV53709772; called by muse, mutect2, varscan2
- ZMIZ2 | c.1890C>T p.L630= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as rs760094901, COSV54808207; called by muse, mutect2, varscan2
- ZNF146 | c.264T>C p.L88= | Silent (SNP) | VAF 48/178 reads (27%) | catalogued as COSV61932024; called by muse, mutect2, varscan2
- ZNF532 | c.822C>T p.I274= | Silent (SNP) | VAF 31/145 reads (21%) | catalogued as rs752823162, COSV60173893; called by muse, mutect2, varscan2
- DNAH8 | c.-41-4549dup | Intron (INS) | VAF 8/20 reads (40%) | catalogued as rs1032638497; called by mutect2, varscan2
- EI24P4 | n.1033C>G | RNA (SNP) | VAF 59/188 reads (31%) | called by muse, mutect2, varscan2
- EIF4A1 | c.205+81C>T | Intron (SNP) | VAF 82/238 reads (34%) | catalogued as rs1054045448, COSV99548934; called by muse, mutect2, varscan2
- EPDR1 | c.-221C>G | 5'UTR (SNP) | VAF 16/51 reads (31%) | catalogued as rs1562854387, COSV52260341; called by muse, mutect2, varscan2
- ESCO1 | c.1954-670G>A | Intron (SNP) | VAF 7/42 reads (17%) | catalogued as rs369884269; called by muse, mutect2, varscan2
- LAIR2 | c.-2C>A | 5'UTR (SNP) | VAF 34/137 reads (25%) | catalogued as COSV100003272; called by muse, mutect2, varscan2
- MACF1 | c.15832-11535G>A | Intron (SNP) | VAF 18/72 reads (25%) | catalogued as COSV57127335; called by muse, mutect2, varscan2
- MYCBPAP | c.-19C>T | 5'UTR (SNP) | VAF 3/16 reads (19%) | catalogued as COSV100088152; called by muse, mutect2
- OBSCN | c.11659+3637T>A | Intron (SNP) | VAF 27/109 reads (25%) | catalogued as COSV99477494; called by muse, mutect2, varscan2
- RNF217-AS1 | n.2568T>C | RNA (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
